Somatic mutation profile of tumor specimen C3L-06316-04 (aliquot CPT0412780006) from CPTAC case C3L-06316, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 65.7 years (23,986 days).
Specimen C3L-06316-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 472251e1-84fd-48cb-86a9-63b3bb33877a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06316-31 (Blood Derived Normal), aliquot CPT0412900005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63bd9942-2d53-4b4d-9c5a-0f3ee1a1d2a0

The open-access MAF lists 91 somatic variants for this specimen: 61 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 27, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906636, CM107219, COSV74204673; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 73/324 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773742788, COSV53896347; called by muse, mutect2
- ANKRD17 | c.7087G>A p.A2363T | Missense Mutation (SNP) | VAF 41/393 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs762523913, COSV58225634; called by muse, mutect2, varscan2
- APC2 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 51/515 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs768815814; called by muse, mutect2
- ATP2B3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1412756906, COSV54842683; called by muse, mutect2
- CACNA1G | c.6128G>A p.R2043Q | Missense Mutation (SNP) | VAF 60/620 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs748384797, COSV61740020; called by muse, mutect2
- CDK20 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1486384814; called by muse, mutect2
- CNTLN | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as rs761699777; called by muse, mutect2, varscan2
- COL20A1 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV58925352; called by muse, mutect2
- CPNE6 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs773704385; called by muse, mutect2
- EPHB1 | c.1171G>A p.V391I | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV67655060, COSV67671851; called by muse, mutect2
- FLT4 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs369939230; called by muse, mutect2, varscan2
- GRID2IP | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 51/580 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1203910154; called by muse, mutect2
- HCN4 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 33/489 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.015); catalogued as rs758437800; called by muse, mutect2
- LRRC36 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as rs768183658, COSV52078528; called by muse, mutect2, varscan2
- MAMDC4 | c.1978C>T p.R660W (on ENST00000445819; = p.R581W on NM_206920.3) | Missense Mutation (SNP) | VAF 30/334 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs374261157; called by muse, mutect2
- MTMR4 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.454); catalogued as rs369882489; called by muse, mutect2
- MYH2 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as rs267604724, COSV55432215; called by muse, mutect2
- PARVA | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 33/427 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs752598937; called by muse, mutect2
- PIAS4 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 65/348 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs779225437; called by muse, mutect2, varscan2
- PLCD4 | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs375491681, COSV68743645; called by muse, mutect2, varscan2
- PTPRS | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 40/632 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.136); catalogued as rs747170106, COSV53619532, COSV99509985; called by muse, mutect2
- RHOBTB2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs747262121, COSV52570387; called by muse, mutect2
- SALL3 | c.3424G>A p.G1142S | Missense Mutation (SNP) | VAF 48/638 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs748568420; called by muse, mutect2
- SARDH | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 43/476 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs751832686; called by muse, mutect2
- SARDH | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 30/547 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs775775395; called by muse, mutect2
- SPATA31E1 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs372694780, COSV57790718, COSV57794674; called by muse, mutect2
- SPEN | c.5576G>A p.R1859Q | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs141410317; called by muse, mutect2, varscan2
- TBATA | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 37/397 reads (9%) | catalogued as rs754558853; called by muse, mutect2
- TET2 | c.3149C>G p.S1050* | Nonsense Mutation (SNP) | VAF 33/418 reads (8%) | catalogued as COSV54436027; called by muse, mutect2
- TMEM132C | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59435796; called by muse, mutect2
- TMEM190 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as COSV52581893, COSV52581976; called by muse, mutect2
- TTN | c.29500G>A p.A9834T (on ENST00000591111; = p.A8907T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/408 reads (7%) | PolyPhen possibly damaging (0.749); catalogued as rs965765805; called by muse, mutect2
- ZNF740 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs1320733516; called by muse, mutect2, varscan2
- ANKRD60 | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- ARNT2 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.097); called by muse, mutect2
- ATP10A | c.3106G>C p.V1036L | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATP8A2 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CELF6 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CFD | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 62/735 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.049); called by muse, mutect2
- DDX11 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, varscan2
- EP400 | c.7816G>T p.V2606F | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ESD | c.626A>T p.K209I | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2
- FAM83C | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 83/469 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRG1 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- GRAMD1A | c.803C>A p.P268Q | Missense Mutation (SNP) | VAF 44/611 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- HSPG2 | c.4258_4259dup p.Y1421Pfs*25 | Frame Shift Ins (INS) | VAF 50/396 reads (13%) | called by mutect2, pindel, varscan2
- IRX6 | c.618del p.E207Rfs*4 | Frame Shift Del (DEL) | VAF 72/651 reads (11%) | called by mutect2, pindel, varscan2
- NOTCH3 | c.6284G>T p.S2095I | Missense Mutation (SNP) | VAF 58/683 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR5A2 | c.1373G>T p.S458I (on ENST00000367362 / NM_205860.3; = p.S412I on NM_003822.5) | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PIK3CB | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- POGLUT3 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMA2 | c.596T>G p.F199C | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCC1 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- SETBP1 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 82/444 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TNKS1BP1 | c.4039G>A p.D1347N | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.203); called by muse, mutect2
- ZBTB44 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 114/482 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIC4 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 35/456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF660 | c.973_975del p.N325del | In Frame Del (DEL) | VAF 26/280 reads (9%) | called by mutect2, pindel
- ZNF99 | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- ADORA2A | c.117C>T p.N39= | Silent (SNP) | VAF 75/468 reads (16%) | catalogued as rs757676705, COSV58379081; called by muse, mutect2, varscan2
- AGRN | c.822G>A p.A274= | Silent (SNP) | VAF 48/508 reads (9%) | called by muse, mutect2
- ALOX15B | c.141G>A p.A47= | Silent (SNP) | VAF 38/308 reads (12%) | catalogued as rs545455096, COSV101205685, COSV66479860; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3081G>A p.S1027= | Silent (SNP) | VAF 36/487 reads (7%) | catalogued as rs368550910; called by muse, mutect2
- ANKLE1 | c.825C>T p.F275= (on ENST00000394458; = p.F221= on NM_152363.6) | Silent (SNP) | VAF 35/506 reads (7%) | catalogued as rs200796739, COSV63920355; called by muse, mutect2
- BMPR1B | c.297G>A p.R99= | Silent (SNP) | VAF 34/400 reads (9%) | called by muse, mutect2
- CLDN11 | c.45C>T p.F15= | Silent (SNP) | VAF 11/366 reads (3%) | catalogued as COSV50355120; called by muse, mutect2
- DSN1 | c.183A>G p.K61= | Silent (SNP) | VAF 27/496 reads (5%) | catalogued as COSV101041127; called by muse, mutect2
- FAM111A | c.1707T>C p.R569= | Silent (SNP) | VAF 20/383 reads (5%) | called by muse, mutect2
- FOXD4L5 | c.822G>A p.S274= | Silent (SNP) | VAF 38/787 reads (5%) | catalogued as rs1230790986; called by muse, mutect2
- HSPG2 | c.11277C>T p.T3759= | Silent (SNP) | VAF 53/610 reads (9%) | catalogued as rs762880860, COSV101013433; called by muse, mutect2
- IRGC | c.192C>T p.G64= | Silent (SNP) | VAF 54/580 reads (9%) | catalogued as rs769031554; called by muse, mutect2
- LGI1 | c.1299C>T p.Y433= | Silent (SNP) | VAF 90/497 reads (18%) | catalogued as rs113679880, COSV65058632; called by muse, mutect2, varscan2
- LHCGR | c.117C>T p.D39= | Silent (SNP) | VAF 33/309 reads (11%) | catalogued as rs1472140371; called by muse, mutect2, varscan2
- LMX1B | c.684G>A p.T228= | Silent (SNP) | VAF 41/480 reads (9%) | catalogued as rs1180709634; called by muse, mutect2
- NTRK2 | c.1482G>A p.S494= (on ENST00000323115 / NM_001369534.1; = p.S510= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/380 reads (14%) | catalogued as rs780047361; called by muse, mutect2, varscan2
- OXR1 | c.2430A>T p.T810= (on ENST00000442977 / NM_001198532.1; = p.T782= on NM_018002.3) | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- PCARE | c.510T>C p.P170= | Silent (SNP) | VAF 50/411 reads (12%) | called by muse, mutect2, varscan2
- PCDH18 | c.1513T>C p.L505= | Silent (SNP) | VAF 36/440 reads (8%) | catalogued as rs1553944726, COSV61268659; called by muse, mutect2
- PCSK2 | c.1689C>T p.D563= | Silent (SNP) | VAF 41/454 reads (9%) | catalogued as rs375983990; called by muse, mutect2
- PRX | c.4317C>T p.S1439= | Silent (SNP) | VAF 48/561 reads (9%) | catalogued as rs372280596, COSV52519116; ClinVar: likely benign; called by muse, mutect2
- PTGFRN | c.2103A>C p.V701= | Silent (SNP) | VAF 77/458 reads (17%) | called by muse, mutect2, varscan2
- SLC17A7 | c.1233C>T p.A411= | Silent (SNP) | VAF 59/388 reads (15%) | catalogued as rs752214392; called by muse, mutect2, varscan2
- SLC7A10 | c.486G>T p.R162= | Silent (SNP) | VAF 60/354 reads (17%) | called by muse, mutect2, varscan2
- SMC1B | c.3153T>C p.C1051= | Silent (SNP) | VAF 24/251 reads (10%) | catalogued as rs1348652883; called by muse, mutect2
- STT3A | c.1458G>A p.P486= | Silent (SNP) | VAF 55/293 reads (19%) | catalogued as rs113134656; called by muse, mutect2, varscan2
- TRPS1 | c.2454T>C p.S818= (on ENST00000220888 / NM_001330599.2; = p.S831= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/411 reads (16%) | called by muse, mutect2, varscan2
- AC004922.1 | c.*148G>A | 3'UTR (SNP) | VAF 20/469 reads (4%) | called by muse, mutect2
- MGAM | c.4619-188G>A | Intron (SNP) | VAF 78/509 reads (15%) | catalogued as rs767992283; called by muse, mutect2, varscan2
- NHSL2 | c.-206-1258C>T | Intron (SNP) | VAF 21/225 reads (9%) | catalogued as rs1419116639, COSV65453180; called by muse, mutect2
